MMRF case MMRF_1456 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2989ecbc-89f5-428b-9b0e-c5ac32a0c309

Demographics
Sex at birth: male; Race: other; Ethnicity: hispanic or latino; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 59.8 years (21,848 days); ISS stage: I; Days to last known disease status: 92 days; Days to last follow up: 92 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 43 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 43 days.

Follow-up (2 entries)
- Days to follow up: -12 days; ECOG performance status: 1.
- Follow-up contact recording only the day: day 92.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- M Protein 3.9 g/dL.
- Leukocytes 5.1 ×10⁹/L.
- C-Reactive Protein 0.7 mg/dL.
- Beta 2 Microglobulin 2.3 µg/mL.
- Total Protein 10.7 g/dL.
- Glucose 12.6 mmol/L.
- Immunoglobulin M 0.14 g/L.
- Absolute Neutrophil 2.96 ×10⁹/L.
- Blood Urea Nitrogen 5 mmol/L.
- Serum Free Immunoglobulin Light Chain, Kappa 1.27 mg/dL.
- Calcium 2.18 mmol/L.
- Lactate Dehydrogenase 5.72 µkat/L.
- Platelets 391 ×10⁹/L.
- Serum Free Immunoglobulin Light Chain, Lambda 62.7 mg/dL.
- Immunoglobulin A 0.32 g/L.
- Creatinine 61.9 µmol/L.
- Albumin 36 g/L.
- Hemoglobin 7.01 mmol/L.
- Immunoglobulin G 52 g/L.

Other clinical attributes
- Day -12: Weight: 67 kg; Height: 165 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1456_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -12 days.
- Sample MMRF_1456_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -12 days.
